Surgical pathology report (de-identified scan), TCGA case TCGA-08-0349, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0349-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0349

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, biopsy: WHO-II glioblastoma multiforme, grade 4; see comment.
- B. Brain, biopsy: WHO-II glioblastoma multiforme, grade 4; see comment.

COMMENT: This glioblastoma multiforme has foci of necrosis with peripheral pseudo-palisading, endothelial proliferation, multiple mitoses and marked nuclear and cytoplasmic pleomorphism, with abundant giant cells. By prior [REDACTED] and [REDACTED] criteria, this is a glioblastoma multiforme. By [REDACTED] criteria, this is a grade 4 astrocytoma. An immunoperoxidase stain for GFAP is positive in many neoplastic astrocytes. A Mib-1 will be performed and an addendum will follow.

Intraoperative Diagnosis

FS1 (A) Temporal lobe, biopsy: Glioblastoma, giant cell type. [REDACTED]

Gross Description

The specimen arrives in two parts, labeled with the patient's name and unit number.

Part A arrives fresh for frozen section analysis, and consists of a portion of soft pink-tan tissue, measuring 1.0 cm in greatest dimension in aggregate. A portion of this tissue is submitted for frozen section analysis and subsequently in cassette A1. The remainder of the unfrozen tissue is submitted in cassette A2.

Part B arrives in formalin, labeled with the patient's name and number and "#1 tumor." It consists of multiple fragments of soft pink-tan and brown tissue, measuring 1.2 cm in greatest dimension and aggregate. This tissue is entirely submitted in cassette B1.

Clinical History

The patient is a [REDACTED] with left temporal mass, consistent with GBM, undergoes right frontoparietal craniotomy.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist

[page 2 of 2]
following review of all patho / slides.

ADDENDUM

Date of Addendum:

Addendum Comment

The MIB-1 immunohistochemical labelling is 35.3%.

The p53 score on this case is 3.

The EGFR score on this case is positive.

Source: NCI Genomic Data Commons file 1d25d5d6-6529-491d-88c1-1d22df2dea93 (TCGA-08-0349.5BF5EA3B-F8EE-411B-8941-7850DDC93A89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).